Surgical pathology report (de-identified scan), TCGA case TCGA-43-8116, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-8116-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Phone [REDACTED]

Procedure: [REDACTED] nal Surgical Pathology Report

Diagnosis

- A. Lymph node, level V, biopsy: There is no evidence of malignancy in any of 3 lymph nodes
- B. Lymph node, level XI, biopsy: A single lymph node is negative for malignancy
- C. Lymph nodes, level VII, biopsy: A single lymph node is negative for malignancy
- D. Lymph node, 4L, biopsy: A single lymph node is negative for malignancy
- E. Lymph node, level 12, biopsy: A single lymph node is negative for malignancy
- F. Lymph node, level IX, biopsy: A single lymph node is negative for malignancy
- G. Lymph node, level VIII, biopsy: A single lymph node is negative for malignancy
- H. Lung, left upper lobe, resection:
Moderately to poorly differentiated squamous cell carcinoma. Emphysema and peritumoral pneumonia.
- I. Lung, left lower lobe, biopsy:
Emphysema, subpleural fibrosis, subpleural bronchiectasis/bronchiolar metaplasia. Negative for malignancy.

Microscopic Description:

H.
Histologic type: Squamous cell carcinoma
Histologic grade: 2-3 out of 3
Mitotic index: 24 mitoses/10 HPFs (1 HPF = 0.196 sq mm)
Tumor size: 3 cm
Bronchial resection margin: Negative for malignancy
Pulmonary margin of resection: []
Pleura: Negative for malignancy
Vascular invasion: Focally present
Attached lymph nodes: A single lymph node is negative for malignancy
pTNM stage: T1b N0
Non-tumorous lung: Peritumoral pneumonia. Emphysema.

Specimen

- A. Level 5 lymph node
- B. Level 11
- C. level VII
- D. 4L node
- E. Level XII
- F. Level IX
- G. Level VIII
- H. Left upper lobe
- I. Left lower lobe nodule

Clinical Information

Squamous cell lung cancer

Intraoperative Consultation

[REDACTED] des, level 5, biopsy: Three benign lymph nodes (0/3). [REDACTED]

[page 2 of 2]
Gross Description

A. Received unfixed for frozen section, labeled level V lymph node, are 3 lymph nodes, 2.0 x 1.0 x 0.6 cm, 1.1 cm in greatest dimension, and 0.6 cm in greatest dimension. Each lymph node is bisected and submitted in a separate block for frozen section (total of three blocks frozen).

B. Specimen B. is received unfixed labeled level XI and consists of 2 pieces of red and black soft tissue measuring 1.5 cm in greatest aggregate dimension.

C. The specimen is received unfixed labeled level VII and consists of 2 pieces of red and black soft tissue measuring 1.3 cm in greatest aggregate dimension. Bisected

D. Specimen D. is received unfixed labeled for-L. node and consists of a piece of red soft tissue measuring 1 by 0.7 x 0.6 cm. Bisected

E. Specimen E. is received unfixed labeled level XII and consists of a reddish-brown piece of soft tissue measuring 1.2 x 0.5 x 0.3 cm. The additional piece of similar appearing tissue measuring 1.2 cm in greatest dimension. The first measurement piece is bisected.

F. The specimen is received unfixed labeled level IX and consists of a red piece of soft tissue measuring 1.2 x 0.7 x 0.2 cm.

G. The specimen is received unfixed labeled level VIII and consists of 3 pieces of red black soft tissue measuring 1.5 cm in greatest aggregate dimension.

H. The specimen is received unfixed labeled left upper lobe is and consists of a 273 g 1 low with red and black serosal surface. The specimen measures 21 x 10.5 x 4 cm. There is a central palpable mass that is 3 cm in diameter by external palpation and roughly spherical. On cut section the tumor is white and 3 cm in diameter. Sections after fixation.

Block summary: 1, 2 bronchial and vascular margins of resection

I. The specimen is received unfixed labeled left lower lobe nodule and consists of a piece of pink and black stapled lung tissue measuring 4.5 by 1.2 x 0.7 cm. Sections after fixation by inflation.

Source: NCI Genomic Data Commons file e4d28631-904b-492c-b6cf-45975fb0b5af (TCGA-43-8116.2038982B-7CFC-4A88-846F-F44F7E8FF78A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).